Gene-level copy-number profile of tumor specimen TCGA-49-4507-01A from TCGA case TCGA-49-4507, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Main bronchus; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 73.5 years (26,851 days).
Specimen TCGA-49-4507-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.0c5e7349-7134-4836-8368-62c596d32e6b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-49-4507-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5e806c1b-a423-43ce-972f-135584fe2d0c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 75; copy number 1: 3,244; copy number 2: 23,169; copy number 3: 25,122; copy number 4: 6,291; copy number 5: 612; copy number 6: 29; copy number 7: 895; copy number 8: 172; copy number 9: 28; copy number 10: 1; copy number 11: 31; copy number 13: 138; copy number 14: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-49-4507-01A-01D-1204-01): tumor purity 0.35, ploidy 2.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,314,246–10,612,723, 1 gene (within-gene range 0–2): PTPRD.
- chr9:9,090,898–9,803,784, 3 genes: RPS26P3, RN7SL5P, AL513422.1.
- chr9:19,789,179–22,455,740, 71 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 910 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,870,866–152,516,008, 24 genes, copy number 7 (within-gene range 5–7): THEM4, AL450992.2, AL450992.3, KRT8P28, S100A10, AL450992.1, NBPF18P, S100A11, SPTLC1P4, AL591893.1, TCHHL1, TCHH, AL589986.1, PUDPP2, RPTN, FLG-AS1, AL589986.2, HRNR, FLG, FLG2, HMGN3P1, CRNN, LCE5A, CRCT1.
- chr12:37,575,587–61,232,937, 741 genes, copy number 7–8 (broad region; genes not listed).
- chr12:61,879,318–61,880,772, 1 gene, copy number 10: KRT8P19.
- chr12:62,643,994–62,935,150, 1 gene, copy number 8 (within-gene range 2–8): PPM1H.
- chr12:62,755,227–68,850,686, 143 genes, copy number 8–11 (within-gene range 2–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,236. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
